CCDI case PBBURI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3110e63a-09b9-4c93-baa5-9481f15f36a6

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.5 years (6,038 days).

Biospecimens (2 samples)
- Sample 0DHTDR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHTEG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
